Gene-level copy-number profile of tumor specimen TCGA-DB-A64X-01A from TCGA case TCGA-DB-A64X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 56.5 years (20,625 days).
Specimen TCGA-DB-A64X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.55ceb3f8-a2cc-41da-920b-9c7407d655e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DB-A64X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49402a94-7361-40f5-92bd-692c3251fb2c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,462; copy number 2: 57,598; copy number 3: 501; copy number 4: 92; copy number 5: 164.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DB-A64X-01A-11D-A323-01): tumor purity 0.94, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 164 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:122,977,026–132,848,807, 159 genes, copy number 5 (broad region; genes not listed).
- chr8:135,234,131–135,742,495, 5 genes, copy number 5: LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.

Autosomal genes at a single copy (total copy number 1): 1,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
